Gene-level copy-number profile of tumor specimen ALCH-B3AW-TTP1-A from ALCHEMIST case ALCH-B3AW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.3 years (24,204 days).
Specimen ALCH-B3AW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file dee12975-7685-4dfc-b1b9-73632b5d3102.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3AW-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,241 have no estimate.
https://portal.gdc.cancer.gov/files/d4a7ed5f-2ab3-49f9-9dc9-d68db1928471

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 199; copy number 1: 11,009; copy number 2: 40,606; copy number 3: 6,202; copy number 4: 327; copy number 5: 26; copy number 6: 11; copy number 21: 2.

Homozygous deletions (total copy number 0; autosomes only): 194 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–145,112,696, 57 genes: AC239859.5, RNA5SP533, AC239859.3, AC239859.4, NKAIN1P1, AC239859.2, LINC02799, AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4, RNVU1-15, AC246785.3, AC246785.2, NBPF15, PFN1P6, AC246785.1, RNVU1-26, RNVU1-2A, RNVU1-28, PPIAL4F, LINC01632, FP700111.1, FP700107.1, RNA5SP59, FP700111.2, FP700111.3, SRGAP2B, AC242498.1, FAM72D.
- chr2:89,884,740–89,887,247, 2 genes: IGKV1D-37, IGKV2D-36.
- chr2:232,343,116–232,382,889, 5 genes (within-gene range 0–2): NRBF2P6, ECEL1P3, AC068134.3, ALPP, AC068134.1.
- chr3:857,124–858,091, 1 gene: AC090044.1.
- chr3:109,326,141–109,410,084, 4 genes (within-gene range 0–2): DPPA4, AC124945.1, AC092905.1, H3P12.
- chr4:4,820,405–4,850,827, 2 genes: AC092437.1, LINC01396.
- chr7:101,299,578–101,321,823, 3 genes: LNCPRESS1, EMSLR, IFT22.
- chr7:102,186,819–102,321,711, 6 genes (within-gene range 0–1): AC005086.4, AC005086.3, AC005086.1, AC005088.1, SH2B2, MIR4285.
- chr7:128,241,278–128,257,629, 1 gene: LEP.
- chr7:140,435,316–140,479,536, 2 genes: AC069335.1, MKRN1.
- chr8:33,523,154–33,580,508, 5 genes: AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P.
- chr9:130,140,610–130,501,274, 5 genes: GPRACR, NCS1, HMCN2, RN7SL665P, ASS1.
- chr10:86,264,694–86,264,788, 1 gene (within-gene range 0–2): MIR346.
- chr12:30,978,308–31,015,806, 2 genes (within-gene range 0–2): AC008013.1, AC008013.2.
- chr12:130,121,925–130,122,974, 1 gene: AC026336.4.
- chr15:25,180,497–25,250,940, 39 genes (within-gene range 0–1): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:77,613,027–77,820,900, 5 genes (within-gene range 0–1): LINGO1, LINGO1-AS1, LINGO1-AS2, AC105133.2, AC105133.1.
- chr17:2,724,411–2,749,504, 3 genes: CCDC92B, MIR1253, hsa-mir-1253.
- chr17:3,977,103–3,981,899, 1 gene: LINC01975.
- chr17:66,964,707–67,033,398, 3 genes: CACNG4, AC005544.1, AC005544.2.
- chr19:29,489,775–29,564,479, 3 genes (within-gene range 0–1): AC011474.2, AC011474.4, VSTM2B.
- chr19:53,666,679–53,682,245, 8 genes: MIR512-1, MIR512-2, MIR1323, MIR498, MIR520E, MIR515-1, MIR519E, MIR520F.
- chr20:47,677,901–47,686,297, 1 gene (within-gene range 0–1): AL354813.1.
- chr22:15,282,557–16,141,872, 34 genes: AP000542.3, AP000542.1, AP000542.2, ZNF72P, BNIP3P2, YME1L1P1, OR11H1, AP000534.2, ARHGAP42P3, AP000534.1, AP000533.2, AP000533.1, AP000533.3, AP000532.2, NEK2P2, AP000532.1, NF1P6, MED15P7, POTEH, POTEH-AS1, RNU6-816P, AP000529.1, PSLNR, GRAMD4P2, DUXAP8, AP000526.1, BMS1P22, AP000525.1, DUXAP8, NBEAP3, TOMM40P2, AP000522.1, AC145543.1, U6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 39 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,646,289–234,736,720, 4 genes, copy number 5 (within-gene range 4–5): AL160408.1, AL160408.4, AL160408.3, LINC01132.
- chr6:32,628,179–32,668,383, 3 genes, copy number 5: HLA-DQA1, HLA-DQB1, HLA-DQB1-AS1.
- chr7:129,225,023–129,430,211, 3 genes, copy number 5: AHCYL2, AC009244.1, CDC26P1.
- chr7:130,791,264–131,110,161, 1 gene, copy number 5 (within-gene range 2–5): AC016831.6.
- chr7:130,938,963–131,110,176, 2 genes, copy number 5 (within-gene range 2–5): LINC-PINT, RNU6-1010P.
- chr7:151,464,650–151,520,120, 3 genes, copy number 5: RN7SL76P, RHEB, ETF1P2.
- chr8:140,657,900–141,002,216, 4 genes, copy number 5: PTK2, MIR151A, AC105235.1, RNA5SP278.
- chr17:18,426,861–18,442,895, 2 genes, copy number 21: KRT17P2, KRT16P1.
- chr17:18,497,095–18,506,313, 1 gene, copy number 5: NOS2P2.
- chr19:1,238,179–1,279,244, 6 genes, copy number 6: AC004221.1, ATP5F1D, MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr20:58,995,185–59,113,631, 5 genes, copy number 5: CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2.
- chr20:64,255,695–64,327,972, 5 genes, copy number 6: PCMTD2, AL137028.2, CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 11,009. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
